FM case AD17671 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adnexal and Skin Appendage Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/0f784008-5579-4aaf-b783-e3224cd44937

Female, 45.4 years: Adnexal carcinoma (ICD-O-3 8390/3) of the skin; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
